Somatic mutation profile of tumor specimen 0DCY0J from CCDI case PBBMSR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 13.9 years (5,074 days).
Specimen 0DCY0J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80f895bb-1381-47a9-b068-1cc3615eaf12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCWB7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/556739c8-19db-433a-b89c-66ee1b57679b

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Nonsense Mutation 2, Intron 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOB | c.11410G>T p.E3804* | Nonsense Mutation (SNP) | VAF 171/621 reads (28%) | catalogued as COSV51932620; called by muse, mutect2, varscan2
- ARMCX4 | c.526G>A p.E176K (on ENST00000433011; = p.E72K on NM_001256155.2) | Missense Mutation (SNP) | VAF 162/645 reads (25%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs1449655521; called by muse, mutect2, varscan2
- CHD7 | c.5243T>C p.L1748P | Missense Mutation (SNP) | VAF 398/861 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV71112771; called by muse, mutect2, varscan2
- KRTAP26-1 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 229/528 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs143081068; called by muse, mutect2, varscan2
- NCKAP5 | c.3151C>T p.R1051C | Missense Mutation (SNP) | VAF 3176/3550 reads (89%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs568273885, COSV58464293; called by muse, varscan2
- SLC6A5 | c.2070+1G>A p.X690_splice | Splice Site (SNP) | VAF 141/301 reads (47%) | catalogued as rs770660705, CD127487, COSV54229382, COSV54232229; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IMPDH2 | c.1281G>C p.Q427H | Missense Mutation (SNP) | VAF 385/858 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- LRP2 | c.11116A>T p.R3706W | Missense Mutation (SNP) | VAF 170/571 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRAMEF9 | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- UGGT2 | c.4298A>G p.N1433S | Missense Mutation (SNP) | VAF 119/609 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- IQCA1 | c.2241C>T p.V747= | Silent (SNP) | VAF 138/486 reads (28%) | catalogued as rs190664020, COSV54510795; called by muse, mutect2, varscan2
- PEAR1 | c.2811C>T p.G937= | Silent (SNP) | VAF 219/610 reads (36%) | catalogued as rs140342582; called by muse, mutect2, varscan2
- RBCK1 | c.723G>A p.A241= (on ENST00000356286 / NM_031229.4; = p.A199= on NM_006462.6) | Silent (SNP) | VAF 704/1184 reads (59%) | catalogued as rs762123098; called by muse, mutect2, varscan2
- KCNAB2 | c.589-97G>A | Intron (SNP) | VAF 7/23 reads (30%) | catalogued as COSV51238961; called by muse, mutect2, varscan2
- TUBB6 | c.*71C>T | 3'UTR (SNP) | VAF 19/80 reads (24%) | catalogued as rs1353405759; called by muse, mutect2, varscan2
